Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7644, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7644-01A (Primary Tumor).

Lab Patient Demographics
(for verification purposes)

Results
SURGICAL PATHOLOGY REPORT

Final

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A. Gallbladder at
- B. Pancreatic duct margin
- C. Bile duct margin
- D. Whipple's
- E. Aortic cable node

Clinical Information

Obstructive jaundice - ERCP - stricture distal bile duct - plastic stent inserted; CT reveals biliary dilatation involving intrahepatic and extrahepatic bile ducts and pancreatic duct markedly dilated and lesion in liver (thought to be cysts) and lymphadenopathy involving iliac region.

Diagnosis

- A. Cholecystectomy:
- Acute cholecystitis
- B. Pancreatic Duct Margin:
- Negative for carcinoma
- C. Bile Duct Margin:
- Negative for carcinoma
- D. Pancreaticoduodenectomy (Whipple Resection), partial pancreas resection:
- Ductal adenocarcinoma of pancreatic head/uncinate process
(please see synoptic)

Source: NCI Genomic Data Commons file c71045b5-723b-4910-acf7-406f5f3cb3fd (TCGA-IB-7644.EDBD392F-EACA-4329-8ABB-94A1315DB088.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).